Somatic mutation profile of tumor specimen 0DWRMX from CCDI case PBCPMH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Spinal cord; Age at diagnosis: 1.2 years (439 days).
Specimen 0DWRMX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c1320f3-d23b-41c1-8dc8-bbc927020965.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWRN0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1140d80-ab87-42d3-80f2-4a0952f9da37

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PNPT1 | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 172/559 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772153760, COSV53177224; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HUNK | c.1922C>T p.P641L | Missense Mutation (SNP) | VAF 318/751 reads (42%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs766424744; called by muse, mutect2, varscan2
- POT1 | c.789T>A p.F263L | Missense Mutation (SNP) | VAF 58/1108 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- XPO7 | c.2664G>A p.Q888= | Silent (SNP) | VAF 269/736 reads (37%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
